Surgical pathology report (de-identified scan), TCGA case TCGA-12-1600, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1600-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

12-1600

Surg Path

CLINICAL HISTORY:

Malignant neoplasm parietal.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section. A 2.5 x 1.4 x 1.4 cm portion of erythematous red-tan soft tissue is received. A representative section is frozen as AF1, frozen remnant submitted in A1. Additional tissue submitted in blocks A2-3. A small portion of tissue is retained in formalin in the specimen container.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue":AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, glomeruloid microvascular proliferation and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (74% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (97% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (31% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (38% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - POLYSOMY (59% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 9 CENTROMERE - POLYSOMY (56% OF TUMOR CELLS EXHIBIT POLYSOMY)

4 OF 4 ABNORMAL MARKERS

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

[page 2 of 2]
BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

12-1600

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A3).

MGMT - POSITIVE (80% OF TUMOR CELLS)

EGFR wt - POSITIVE (3+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (3+ IN 40% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 50% OF TUMOR CELLS)

pS6 - NEGATIVE (2+ IN 10% OF TUMOR CELLS)

pAKT - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file dfc6c0b6-c6b1-43b1-bd9c-ea863bab0fa9 (TCGA-12-1600.A65A18CF-E941-4062-9ED1-8C8F3CEC9AE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).